Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A6EZ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A6EZ-01A (Primary Tumor).

Department of Cancer Pathology

ICD-O-3
Adenocarcinoma, intestinal type
Site ^{C64} Gastric fundus 8144/3
^{K05} Stomach NOS 016.9
8/19/13

Patient: [REDACTED] Age: Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Gastric cancer**

Date of admission:

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological diagnosis

Examination performed on:

Invasive stomach adenocarcinoma (G3), pT3, pN2.
Cancer metastases to lymph nodes No III/XVII. (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 25 x 22 cm with the omentum sized 59 x 28 cm.
Medallion shaped tumour sized 5.5 x 6 x 1.3 cm on the back wall.
The infiltration visibly crosses the stomach wall.
Distance from the proximal end 5.2 cm, from distal end, 4.7 cm.

Microscopic description:

Adenocarcinoma invasivum ventriculi (G3).
(Intestinal type acc. to Lauren) Tumour penetrates the full thickness of the stomach wall, without invading the peritoneum. Surgical excision lines are within the area of healthy tissue.
Vessels invaded.
Fat tissue uninvolved.
Lymph nodes:
1.2- (cardia) - Lymphonodulitis reactiva No I.
3 (lesser curvature): Metastases carcinomatosae in lymphonodis No II/VIII.
4 (greater curvature) - Lymphonodulitis reactiva No VII.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Reviewed: Kml	Date Reviewed: 8/19/13	

Source: NCI Genomic Data Commons file 0e6a4163-0758-4396-9140-3943c22891b6 (TCGA-D7-A6EZ.F0E73D2B-60E7-4651-8986-92D4E123892A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).